Gene-level copy-number profile of tumor specimen TCGA-FD-A3SR-01A from TCGA case TCGA-FD-A3SR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.4 years (24,979 days).
Specimen TCGA-FD-A3SR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.7138d578-9d2e-48be-a154-003bc404ae8c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3SR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6b1b688-b380-47b0-b0f8-9513daddc3ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 2,385; copy number 2: 17,920; copy number 3: 23,754; copy number 4: 9,271; copy number 5: 3,422; copy number 6: 422; copy number 7: 271; copy number 8: 2,142; copy number 9: 57; copy number 10: 53; copy number 14: 66; copy number 18: 30; copy number 19: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3SR-01A-11D-A22Y-01): tumor purity 0.57, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–465,259, 11 genes (within-gene range 0–1): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,625 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–181,839,774, 1,240 genes, copy number 8 (broad region; genes not listed).
- chr1:245,154,985–245,709,432, 1 gene, copy number 8 (within-gene range 5–8): KIF26B.
- chr1:245,614,773–248,919,946, 138 genes, copy number 8 (broad region; genes not listed).
- chr5:321,759–2,119,926, 64 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:37,559,992–42,207,709, 116 genes, copy number 7–10 (broad region; genes not listed).
- chr9:3,526,723–3,691,814, 3 genes, copy number 7 (within-gene range 1–7): RFX3-AS1, AL354977.2, AL354977.1.
- chr9:3,875,584–3,901,248, 2 genes, copy number 7: AL137071.1, GLIS3-AS1.
- chr9:6,532,467–6,727,438, 11 genes, copy number 7: GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes, copy number 7: PRELID3BP11, SNRPEP2.
- chr10:6,737,418–6,840,712, 1 gene, copy number 9 (within-gene range 6–9): AL392086.2.
- chr10:6,779,549–10,462,361, 44 genes, copy number 9–18 (within-gene range 6–18): LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.
- chr10:42,149,310–47,002,488, 147 genes, copy number 7 (broad region; genes not listed).
- chr16:7,878,799–9,518,325, 34 genes, copy number 9–14 (within-gene range 2–14): AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195.
- chr16:23,278,231–24,827,632, 37 genes, copy number 14 (within-gene range 2–14): SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2, NDUFAB1, PALB2, AC008870.4, DCTN5, AC008870.1, PLK1, AC008870.3, ERN2, AC008870.5, AC012317.1, AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567.
- chr18:47,390–2,049,510, 46 genes, copy number 8–10 (within-gene range 5–10): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1.
- chr18:1,927,727–1,929,094, 1 gene, copy number 10: AIDAP3.
- chr18:2,621,090–4,455,307, 43 genes, copy number 9–19 (within-gene range 5–19): Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5.
- chr18:5,237,826–5,290,608, 1 gene, copy number 10 (within-gene range 5–10): LINC00667.
- chr18:5,289,019–9,402,420, 74 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr19:33,302,857–45,410,737, 620 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
